Somatic mutation profile of cancer-model specimen HCM-CSHL-0516-C56-85B (3D Organoid, passage 3; aliquot HCM-CSHL-0516-C56-85B-01D-A82H-36), derived from the primary tumor of HCMI case HCM-CSHL-0516-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous cystic tumor of borderline malignancy; Tissue or organ of origin: Ovary.
Specimen HCM-CSHL-0516-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df2b431b-8fe2-40c3-8351-aa705f87f4cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0516-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0516-C56-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f482018-f983-4f05-82bc-30307447d09f

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Intron 1, 3'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 134/273 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AMPD1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 142/321 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147852547; called by muse, mutect2, varscan2
- ARHGAP4 | c.1972G>A p.V658M | Missense Mutation (SNP) | VAF 268/585 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs782046575, COSV61685713; called by muse, mutect2, varscan2
- BMP4 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 55/565 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1268997444, COSV55416241; called by muse, mutect2
- CYP11A1 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 131/271 reads (48%) | catalogued as rs765916701; called by muse, mutect2, varscan2
- DENND2C | c.2206G>A p.V736M (on ENST00000393274 / NM_001256404.2; = p.V679M on NM_198459.4) | Missense Mutation (SNP) | VAF 33/396 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs775405891; called by muse, mutect2
- DHX36 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV57674711; called by muse, mutect2, varscan2
- GFOD1 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 180/413 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.564); catalogued as COSV64954362; called by muse, mutect2, varscan2
- GGN | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 39/774 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771674743; called by muse, mutect2
- IMPACT | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 151/325 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs775241575; called by muse, mutect2, varscan2
- OR10Z1 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100778959; called by muse, mutect2, varscan2
- OR2T1 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 55/487 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63542314; called by muse, mutect2, varscan2
- PEG3 | c.2888G>A p.R963H | Missense Mutation (SNP) | VAF 177/387 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs369854592, COSV55632454; called by muse, mutect2, varscan2
- SPTBN4 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 30/628 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs781430619; called by muse, mutect2
- TENM3 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as rs374213747; called by muse, mutect2, varscan2
- TRIO | c.5437G>A p.G1813S | Missense Mutation (SNP) | VAF 22/660 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs1025988315; called by muse, mutect2
- DGKZ | c.2953G>A p.E985K (on ENST00000454345 / NM_001105540.2; = p.E797K on NM_003646.4) | Missense Mutation (SNP) | VAF 132/292 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DOCK10 | c.3983A>G p.K1328R | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FUZ | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 144/304 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- GRK4 | c.296G>C p.S99T (on ENST00000398052 / NM_182982.3; = p.S67T on NM_005307.3) | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- KDM6A | c.3268dup p.L1090Pfs*3 | Frame Shift Ins (INS) | VAF 102/254 reads (40%) | called by mutect2, pindel, varscan2
- KHDC4 | c.1008A>T p.L336F | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- RBM10 | c.1665del p.T556Lfs*148 | Frame Shift Del (DEL) | VAF 210/502 reads (42%) | called by mutect2, pindel, varscan2
- SACS | c.7372C>T p.L2458F | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TBC1D32 | c.3589T>A p.F1197I | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- TMEM108 | c.1154C>A p.A385D | Missense Mutation (SNP) | VAF 40/334 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- YAP1 | c.137A>T p.Q46L | Missense Mutation (SNP) | VAF 345/676 reads (51%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF676 | c.1447T>A p.C483S (on ENST00000650058; = p.C451S on NM_001001411.3) | Missense Mutation (SNP) | VAF 178/401 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANTXRL | c.504C>T p.S168= | Silent (SNP) | VAF 32/258 reads (12%) | catalogued as rs1192984458; called by muse, mutect2, varscan2
- COL6A5 | c.5511C>A p.T1837= (on ENST00000312481; = p.T1833= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 161/328 reads (49%) | called by muse, mutect2, varscan2
- DNAH11 | c.9318A>T p.L3106= | Silent (SNP) | VAF 137/306 reads (45%) | called by muse, mutect2, varscan2
- ERVFRD-1 | c.1107C>T p.T369= | Silent (SNP) | VAF 119/283 reads (42%) | catalogued as rs1189602788, COSV65370010; called by muse, mutect2, varscan2
- PLEC | c.8988C>T p.H2996= (on ENST00000322810 / NM_201380.4; = p.H2886= on NM_000445.5) | Silent (SNP) | VAF 61/548 reads (11%) | catalogued as rs200012425, COSV59624550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RXFP1 | c.1074C>A p.I358= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100314179, COSV100314351; called by muse, mutect2, varscan2
- SLC25A53 | c.267G>A p.T89= | Silent (SNP) | VAF 214/419 reads (51%) | catalogued as rs782234735, COSV62460462; called by muse, mutect2, varscan2
- USP31 | c.2403G>T p.V801= | Silent (SNP) | VAF 40/530 reads (8%) | called by muse, mutect2
- IGFN1 | c.1242-660C>T | Intron (SNP) | VAF 25/459 reads (5%) | catalogued as rs137917527; called by muse, mutect2
- PRDM11 | chr11:45226890 G>T | 3'Flank (SNP) | VAF 203/432 reads (47%) | called by muse, mutect2, varscan2
